Somatic mutation profile of tumor specimen TCGA-AK-3426-01A (aliquot TCGA-AK-3426-01A-02D-1386-10) from TCGA case TCGA-AK-3426, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 37.7 years (13,770 days).
Specimen TCGA-AK-3426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea131ae-45a0-4092-bd23-5b83062ef167.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3426-10A (Blood Derived Normal), aliquot TCGA-AK-3426-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe2abbf5-172e-465e-8985-66338056e958

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELOC | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 48/287 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV53022646, COSV53022661, COSV53024355; called by muse, mutect2, varscan2
- ACLY | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV100709549, COSV100709574; called by muse, mutect2
- C1S | c.1075T>G p.C359G | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196403; called by muse, mutect2
- C9 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99661748; called by muse, mutect2, varscan2
- CLCA4 | c.2505A>C p.E835D | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.446); catalogued as COSV100991068, COSV100991181; called by muse, mutect2, varscan2
- CNGA3 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99736199; called by muse, mutect2, varscan2
- GRIK4 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); catalogued as rs373728384; called by muse, mutect2, varscan2
- LRRC66 | c.1186T>G p.F396V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100602846; called by muse, mutect2, varscan2
- MMRN1 | c.2746A>T p.N916Y | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV99306604; called by muse, mutect2, varscan2
- NXF1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99585812; called by muse, mutect2, varscan2
- PNP | c.508A>C p.M170L | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369994873; called by muse, mutect2, varscan2
- SBF2 | c.4936A>G p.I1646V | Missense Mutation (SNP) | VAF 96/613 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV99813404; called by muse, varscan2
- SCAMP3 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1216069611, COSV100226602; called by muse, mutect2
- STAT4 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 40/266 reads (15%) | catalogued as COSV100635980; called by muse, mutect2, varscan2
- TRIP11 | c.5222A>C p.D1741A | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99970402; called by muse, mutect2, varscan2
- YARS2 | c.684C>G p.D228E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256321; called by muse, mutect2, varscan2
- ZBED8 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV101283469; called by muse, mutect2, varscan2
- DCDC1 | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GTPBP4 | c.1232del p.L411Wfs*9 | Frame Shift Del (DEL) | VAF 136/800 reads (17%) | called by mutect2, pindel, varscan2
- ALMS1 | c.7401G>A p.E2467= | Silent (SNP) | VAF 61/398 reads (15%) | catalogued as COSV100041391; called by muse, mutect2, varscan2
- BMP3 | c.1125C>A p.L375= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV99261439; called by muse, mutect2, varscan2
- CDKL3 | c.183C>T p.N61= | Silent (SNP) | VAF 45/290 reads (16%) | catalogued as COSV99527662; called by muse, mutect2, varscan2
- DAB2 | c.2121A>G p.L707= | Silent (SNP) | VAF 73/440 reads (17%) | catalogued as rs1252745142, COSV100297812; called by muse, mutect2, varscan2
- KCNAB1 | c.921C>T p.Y307= (on ENST00000490337 / NM_172160.3; = p.Y296= on NM_003471.3) | Silent (SNP) | VAF 71/478 reads (15%) | catalogued as rs375830651; called by muse, mutect2, varscan2
- NIBAN3 | c.1362A>T p.A454= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV99961866; called by muse, mutect2, varscan2
- PTPRK | c.3519C>T p.L1173= (on ENST00000368215 / NM_001291984.2; = p.L1174= on NM_002844.4) | Silent (SNP) | VAF 61/274 reads (22%) | catalogued as COSV100950485; called by muse, mutect2, varscan2
- SRRM2 | c.8256A>G p.P2752= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV99241278; called by muse, mutect2
- ZNF467 | c.396C>T p.A132= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs771487182, COSV100117794; called by muse, varscan2
